Somatic mutation profile of tumor specimen TARGET-10-PANVMT-09A (aliquot TARGET-10-PANVMT-09A-01D) from TARGET case TARGET-10-PANVMT, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.2 years (3,359 days).
Specimen TARGET-10-PANVMT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aefeb0f7-c75a-4d13-8ff0-8a326e644f4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANVMT-14A (Bone Marrow Normal), aliquot TARGET-10-PANVMT-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b466bf14-d660-4ab2-8d0b-cd1829d2c309

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 1, 3'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGO2 | c.1388C>T p.T463M | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs1487711892; called by mutect2, varscan2
- TP53 | c.843_844insGCC p.D281_R282insA | In Frame Ins (INS) | VAF 14/94 reads (15%) | catalogued as COSV52854501; called by mutect2, pindel, varscan2
- ASXL3 | c.4969C>A p.P1657T | Missense Mutation (SNP) | VAF 8/216 reads (4%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); called by muse, mutect2
- ECT2 | c.660T>C p.N220= (on ENST00000392692 / NM_001349098.2; = p.N189= on NM_018098.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as rs1435479046; called by muse, mutect2, varscan2
- RPS6KL1 | c.*127C>T | 3'UTR (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
